Somatic mutation profile of tumor specimen TCGA-5P-A9JY-01A (aliquot TCGA-5P-A9JY-01A-11D-A42J-10) from TCGA case TCGA-5P-A9JY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 79.1 years (28,881 days).
Specimen TCGA-5P-A9JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96cadbec-b135-419b-becb-24dd09243392.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9JY-10A (Blood Derived Normal), aliquot TCGA-5P-A9JY-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfb56b1d-ccc0-4aba-b960-63e855c375f9

The open-access MAF lists 118 somatic variants for this specimen: 96 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 63, Silent 22, Frame Shift Del 17, In Frame Del 4, Splice Site 3, Frame Shift Ins 3, Nonsense Mutation 3, Splice Region 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL18A1 | c.3918del p.G1307Dfs*17 (on ENST00000359759 / NM_130444.3; = p.G1072Dfs*17 on NM_030582.4) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- AASDH | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV99220754; called by muse, mutect2, varscan2
- ADI1 | c.120G>A p.K40= | Splice Region (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100537686; called by muse, mutect2, varscan2
- AKIRIN1 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); catalogued as COSV100881972; called by muse, mutect2, varscan2
- AQR | c.1915A>C p.T639P | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.274); catalogued as COSV99333139; called by muse, mutect2, varscan2
- ARHGEF28 | c.4347G>T p.Q1449H | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99708112; called by muse, mutect2, varscan2
- ARID3A | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV99708228; called by muse, varscan2
- ATP6V0A1 | c.424-1G>T p.X142_splice | Splice Site (SNP) | VAF 73/133 reads (55%) | catalogued as COSV99230441; called by muse, mutect2, varscan2
- ATP8B2 | c.1750C>G p.P584A (on ENST00000672630; = p.P551A on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV100527632; called by muse, mutect2, varscan2
- ATXN2 | c.2003C>G p.P668R (on ENST00000550104; = p.P508R on NM_002973.4) | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV101112566; called by muse, mutect2, varscan2
- BTBD3 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99655609; called by muse, mutect2, varscan2
- BTN2A1 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100438365; called by muse, mutect2, varscan2
- C16orf72 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1389202549, COSV100588955; called by muse, mutect2, varscan2
- CACNA1B | c.6574C>T p.Q2192* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99495046; called by muse, mutect2, varscan2
- CAND1 | c.1291C>A p.Q431K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV101598259; called by muse, mutect2, varscan2
- CDK1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100358756; called by muse, mutect2, varscan2
- CEP131 | c.177G>A p.L59= | Splice Region (SNP) | VAF 16/115 reads (14%) | catalogued as COSV99487801; called by muse, mutect2, varscan2
- CYP51A1 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 174/540 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99133573; called by muse, mutect2, varscan2
- DISP3 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99607259; called by muse, mutect2, varscan2
- DNAJB9 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99974363; called by mutect2, varscan2
- DPP9 | c.962A>C p.E321A (on ENST00000598800; = p.E350A on NM_139159.5) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99505674; called by muse, mutect2, varscan2
- FBLN5 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.667); catalogued as COSV99969301; called by muse, mutect2, varscan2
- FCHO1 | c.438G>C p.M146I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99405794; called by muse, mutect2, varscan2
- GNG13 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs988805496, COSV99242137; called by muse, mutect2, varscan2
- HNRNPC | c.873G>T p.E291D (on ENST00000420743; = p.E278D on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as COSV100192828; called by muse, mutect2, varscan2
- HSPD1 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV99291341; called by muse, varscan2
- HSPH1 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184641; called by muse, mutect2, varscan2
- IGLV3-22 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762895873; called by muse, mutect2
- KCNQ2 | c.2119G>A p.A707T (on ENST00000359125 / NM_172107.4; = p.A679T on NM_004518.6) | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs543477138, COSV60544464; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KDELR3 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53249244, COSV99318038; called by muse, mutect2, varscan2
- KNTC1 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV100337904; called by muse, mutect2, varscan2
- KRTAP10-7 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs782290027, COSV100169986; called by muse, mutect2, varscan2
- KRTAP4-3 | c.43T>A p.C15S | Missense Mutation (SNP) | VAF 99/143 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101194135, COSV66940892; called by muse, mutect2, varscan2
- LAMB4 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs766405251, COSV52713231; called by muse, mutect2, varscan2
- LAMC1 | c.3251A>G p.D1084G | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV99278917; called by muse, mutect2, varscan2
- LZTR1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs970027059, COSV99301246; called by muse, mutect2, varscan2
- MAN1B1 | c.1186del p.A396Pfs*3 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as COSV65379019; called by mutect2, pindel, varscan2
- MAP3K6 | c.2463G>T p.Q821H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV100539098; called by muse, mutect2, varscan2
- MED14 | c.3232A>G p.I1078V | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs755442697, COSV100247286; called by muse, mutect2, varscan2
- MMP27 | c.1481G>C p.S494T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV99498231; called by muse, mutect2, varscan2
- MYO1F | c.997C>G p.R333G | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100596332, COSV57791743; called by muse, mutect2, varscan2
- NAV3 | c.6703G>T p.D2235Y (on ENST00000397909 / NM_001024383.2; = p.D2213Y on NM_014903.6) | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57097266, COSV99886726; called by muse, mutect2, varscan2
- NF1 | c.5494G>A p.E1832K (on ENST00000358273 / NM_001042492.3; = p.E1811K on NM_000267.3) | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as CS1311532, COSV100645978; called by muse, mutect2, varscan2
- NKX6-1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV99879902; called by muse, varscan2
- NLRC3 | c.2795A>G p.D932G | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100072402; called by muse, mutect2, varscan2
- PCDHGA2 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.458); catalogued as rs763304027, COSV99530101; called by muse, mutect2, varscan2
- PKHD1 | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs112182862, COSV100580961; ClinVar: uncertain significance; called by muse, mutect2
- PNRC1 | c.884A>T p.K295M | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100259750; called by muse, mutect2, varscan2
- PPARG | c.733C>T p.H245Y (on ENST00000287820 / NM_015869.5; = p.H215Y on NM_005037.7) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as COSV99826280; called by muse, mutect2, varscan2
- PPP1R21 | c.2230A>C p.M744L (on ENST00000294952 / NM_001135629.3; = p.M733L on NM_152994.5) | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV99681630; called by muse, mutect2, varscan2
- RBM19 | c.1819T>A p.F607I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99925473; called by muse, mutect2, varscan2
- RRM1 | c.1118G>C p.S373T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100331212, COSV100331244; called by muse, mutect2, varscan2
- RUSC2 | c.1878C>A p.H626Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs773892257, COSV100770590; called by muse, mutect2, varscan2
- SESN1 | c.809T>C p.F270S (on ENST00000356644 / NM_001199933.1; = p.F329S on NM_014454.3) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100122664; called by muse, mutect2, varscan2
- SLC23A3 | c.1484A>G p.Q495R (on ENST00000409878 / NM_001144889.2; = p.Q378R on NM_144712.5) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV99840849; called by muse, mutect2, varscan2
- SNX29 | c.2041T>A p.Y681N | Missense Mutation (SNP) | VAF 160/276 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100027151; called by muse, mutect2, varscan2
- TCP11L1 | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV100177797; called by muse, mutect2, varscan2
- TERF2IP | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as COSV100265675; called by muse, mutect2, varscan2
- TLE2 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99504008; called by muse, mutect2, varscan2
- TPRA1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99952262; called by muse, mutect2, varscan2
- TREML1 | c.384A>T p.E128D | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.156); catalogued as COSV100914267; called by muse, mutect2, varscan2
- TTN | c.102974G>T p.G34325V (on ENST00000591111; = p.G26901V on NM_003319.4) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | PolyPhen possibly damaging (0.656); catalogued as COSV100593255; called by muse, mutect2, varscan2
- UPF3A | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV100677516; called by muse, mutect2, varscan2
- USP34 | c.9806A>C p.Y3269S | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV100815932; called by muse, mutect2, varscan2
- VPS13D | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.363); catalogued as COSV100692361; called by muse, mutect2, varscan2
- WASHC2C | c.1932A>T p.E644D | Missense Mutation (SNP) | VAF 148/407 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100313778, COSV60493809; called by muse, mutect2, varscan2
- WDR20 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs374240865; called by muse, mutect2, varscan2
- ZFAT | c.1750T>C p.S584P | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.059); catalogued as COSV100914183; called by muse, mutect2, varscan2
- ZNF146 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100757627; called by muse, mutect2, varscan2
- ZNF24 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as rs1464159015, COSV99734165; called by muse, mutect2, varscan2
- ZRANB2 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV99638902; called by muse, mutect2, varscan2
- ZSWIM4 | c.356-1G>T p.X119_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99584479; called by muse, mutect2
- ACTR8 | c.211_221delinsC p.I71Pfs*20 | Frame Shift Del (DEL) | VAF 47/155 reads (30%) | called by pindel, varscan2*
- ANO8 | c.1333_1334del p.Q445Vfs*87 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by mutect2, varscan2
- BABAM2 | c.767_775dup p.T258_N259insMLT | In Frame Ins (INS) | VAF 14/25 reads (56%) | called by mutect2, varscan2
- C10orf71 | c.1627_1629del p.I543del | In Frame Del (DEL) | VAF 39/104 reads (38%) | called by mutect2, pindel, varscan2
- CCSER1 | c.437dup p.N146Kfs*13 | Frame Shift Ins (INS) | VAF 59/163 reads (36%) | called by mutect2, pindel, varscan2
- CHST2 | c.1093del p.R365Afs*83 | Frame Shift Del (DEL) | VAF 34/123 reads (28%) | called by mutect2, pindel, varscan2
- CMBL | c.389_390del p.G130Vfs*32 | Frame Shift Del (DEL) | VAF 28/58 reads (48%) | called by mutect2, varscan2
- CNNM2 | c.995del p.I332Tfs*15 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- CPNE2 | c.283_298del p.L95Sfs*35 | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | called by mutect2, pindel, varscan2
- CYP2C18 | c.413_415delinsG p.K138Rfs*27 | Frame Shift Del (DEL) | VAF 70/169 reads (41%) | called by pindel, varscan2*
- DMC1 | c.267del p.F89Lfs*24 | Frame Shift Del (DEL) | VAF 49/129 reads (38%) | called by mutect2, pindel, varscan2
- ELP1 | c.3358del p.Y1120Ifs*21 | Frame Shift Del (DEL) | VAF 43/112 reads (38%) | called by mutect2, pindel, varscan2
- HELQ | c.223dup p.L75Pfs*7 | Frame Shift Ins (INS) | VAF 50/148 reads (34%) | called by mutect2, pindel, varscan2
- KCNJ15 | c.285dup p.E96Rfs*4 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | called by mutect2, pindel, varscan2
- MPND | c.1098_1101delinsT p.Q366_M367delinsH | In Frame Del (DEL) | VAF 35/86 reads (41%) | called by pindel, varscan2*
- NOP2 | c.665_668del p.P222Lfs*45 (on ENST00000322166 / NM_001258308.2; = p.P218Lfs*45 on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | called by mutect2, pindel, varscan2
- PCGF2 | c.1029_1033del p.T344Rfs*43 | Frame Shift Del (DEL) | VAF 55/207 reads (27%) | called by mutect2, pindel, varscan2
- PER3 | c.92del p.F31Sfs*32 | Frame Shift Del (DEL) | VAF 80/211 reads (38%) | called by mutect2, pindel, varscan2
- PPCDC | c.476_477del p.F159Wfs*17 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- RD3 | c.182_198del p.S61Tfs*6 | Frame Shift Del (DEL) | VAF 63/167 reads (38%) | called by mutect2, pindel, varscan2
- TMEM242 | c.254_259del p.W85_G86del | In Frame Del (DEL) | VAF 100/233 reads (43%) | called by mutect2, varscan2
- TRIP12 | c.4035del p.Q1345Hfs*13 | Frame Shift Del (DEL) | VAF 70/217 reads (32%) | called by mutect2, pindel, varscan2
- TRPM8 | c.2589+2_2589+3insTTT p.X863_splice | Splice Site (INS) | VAF 51/103 reads (50%) | called by mutect2, pindel, varscan2
- UBN1 | c.3218_3223del p.I1073_V1074del | In Frame Del (DEL) | VAF 47/90 reads (52%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.6531G>T p.V2177= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99292244; called by muse, mutect2, varscan2
- CA12 | c.645C>T p.T215= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs770126076, COSV51608623, COSV99457882; called by muse, mutect2, varscan2
- CCL4L2 | c.18T>A p.T6= | Silent (SNP) | VAF 232/249 reads (93%) | called by muse, mutect2, varscan2
- CEL | c.84C>T p.A28= (on ENST00000673714; = p.A25= on NM_001807.6) | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as rs1200826239, COSV100672216; called by muse, mutect2
- COMMD10 | c.297T>A p.I99= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV99174499; called by muse, mutect2, varscan2
- DDX58 | c.2088C>T p.A696= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs767862296, COSV101152431; called by muse, mutect2, varscan2
- DISP3 | c.2580G>T p.V860= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV99607264; called by muse, mutect2, varscan2
- KDELR3 | c.402G>A p.Q134= | Silent (SNP) | VAF 47/81 reads (58%) | catalogued as COSV99318043; called by muse, mutect2, varscan2
- KTN1 | c.420C>G p.G140= | Silent (SNP) | VAF 148/338 reads (44%) | catalogued as COSV101254961; called by muse, varscan2
- MYD88 | c.252C>A p.A84= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV100085762; called by muse, mutect2, varscan2
- MYH10 | c.3612C>A p.A1204= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99343991; called by muse, mutect2, varscan2
- OR8G1 | c.792A>T p.S264= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs985733945, COSV100422207; called by muse, mutect2, varscan2
- OSBPL5 | c.2364C>G p.L788= | Silent (SNP) | VAF 103/191 reads (54%) | catalogued as COSV99719990; called by muse, mutect2, varscan2
- PLIN3 | c.1185C>A p.A395= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs753453574, COSV99701445; called by muse, mutect2, varscan2
- PWWP2B | c.1452C>T p.D484= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as rs201677128, COSV59453046; called by muse, mutect2
- RNF213 | c.13998A>G p.T4666= | Silent (SNP) | VAF 94/154 reads (61%) | catalogued as COSV100299637; called by muse, mutect2, varscan2
- SFPQ | c.867A>G p.G289= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV100599270; called by muse, mutect2, varscan2
- SLC10A5 | c.1032T>C p.P344= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV101594242; called by muse, mutect2, varscan2
- SPAG7 | c.10C>T p.L4= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs748946978, COSV99236161; called by muse, mutect2, varscan2
- TNFRSF18 | c.54G>T p.L18= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV100148799; called by muse, mutect2, varscan2
- USP24 | c.2853T>C p.H951= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV99598768; called by muse, mutect2, varscan2
- USP34 | c.7884G>A p.L2628= | Silent (SNP) | VAF 48/308 reads (16%) | catalogued as COSV101276622; called by muse, mutect2, varscan2
